Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A1MK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A1MK-01A (Primary Tumor).

1CD-0-3
Carcinoma, squamous cell, NOS 8070/3
Site: cervix, NOS C53.9 2/24/11 hr

SURGICAL PATHOLOGY REPORT FINAL

Patient Name:

Address:

Gender: F

DOB:

Service: Obstetrics

Location:

MRN:

Hospital #:

Patient Type:

Accession #

Taken:

Received:

Accessioned:

Reported:

Physician(s): M.D.

DIAGNOSIS:

UTERUS, CERVIX, BIOPSY

- MODERATELY TO POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

M.D.

***Report Electronically Reviewed and Signed Out By

M.D.

Microscopic Description and Comment:

Sections of the cervical biopsy show a moderately to poorly differentiated squamous cell carcinoma. The tumor is poorly keratinized.

M.D.

History:

The patient is a year old woman diagnosed with cervical mass. Operative procedure: Cervical biopsy.

Specimen(s) Received:

A: CERVIX

Gross Description:

The specimen is received in a formalin-filled container labeled "cervical biopsy." It consists of irregular tan tissue fragments, admixed with gray-white mucoid material, aggregating to 0.7 x 0.5 x 0.3 cm. Labeled A. Jar 0.

M.S.

Surgical Pathology report is available on-line or

and Clinical Desktop.

The performance characteristics of some instruments used in this report (if any) were determined by the manufacturer.

Not to part of an ongoing quality assurance program and in compliance with laboratory

only specific requests and are subject to specific labeling requirements by the US Post and Drug Administration. Such diagnostic tests may only be performed in a facility

Source: NCI Genomic Data Commons file 5534ecdb-2937-4964-be2c-068213144f80 (TCGA-C5-A1MK.75B6D26C-3C3C-4D2E-BFDD-C9CB81AE3793.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).